Somatic mutation profile of tumor specimen TCGA-AR-A0TY-01A (aliquot TCGA-AR-A0TY-01A-12W-A12T-09) from TCGA case TCGA-AR-A0TY, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 54.3 years (19,836 days).
Specimen TCGA-AR-A0TY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1bfec90-21f6-4c3f-8751-81571d1d8d83.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A0TY-10A (Blood Derived Normal), aliquot TCGA-AR-A0TY-10A-01D-A110-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/777b5ead-ecbb-4e6a-b685-4f59b5a69f1c

The open-access MAF lists 73 somatic variants for this specimen: 55 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 16, Frame Shift Ins 7, Nonsense Mutation 4, Frame Shift Del 2, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM23 | c.2340dup p.K781Qfs*3 | Frame Shift Ins (INS) | VAF 18/158 reads (11%) | catalogued as rs767549806; called by mutect2, varscan2
- ADARB1 | c.1622C>T p.T541M (on ENST00000360697 / NM_001346687.2; = p.T501M on NM_001112.4) | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV62344288; called by muse, mutect2, varscan2
- ADGRF1 | c.2191G>T p.D731Y | Missense Mutation (SNP) | VAF 69/198 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV51944669, COSV51945500; called by muse, mutect2, varscan2
- ALK | c.903G>A p.M301I | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV66595291; called by muse, mutect2
- ALMS1 | c.4340A>G p.H1447R | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.049); catalogued as COSV52509879; called by muse, mutect2, varscan2
- ATG16L2 | c.971T>C p.L324P | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV58361705; called by muse, mutect2, varscan2
- BPIFB4 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as rs143050216; called by muse, mutect2, varscan2
- CCDC144A | c.3717T>A p.N1239K | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV60698243; called by muse, mutect2, varscan2
- CDC20B | c.398C>G p.S133C | Missense Mutation (SNP) | VAF 140/454 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV99696392; called by muse, mutect2
- CDH9 | c.1220C>A p.A407E | Missense Mutation (SNP) | VAF 15/216 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50353323; called by muse, mutect2
- CFAP43 | c.1327T>A p.S443T | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.046); catalogued as COSV53377914; called by muse, mutect2, varscan2
- CIT | c.4592C>T p.P1531L | Missense Mutation (SNP) | VAF 29/560 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.47); catalogued as rs1472431033, COSV99948004; called by muse, mutect2
- CLDN11 | c.46G>A p.V16M | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.418); catalogued as rs1158887033, COSV50355425; called by muse, mutect2, varscan2
- CPNE4 | c.626C>A p.S209* | Nonsense Mutation (SNP) | VAF 41/144 reads (28%) | catalogued as COSV70194258; called by muse, mutect2, varscan2
- CRABP1 | c.248G>C p.R83T | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV55115797; called by muse, mutect2, varscan2
- CTNND2 | c.2892C>A p.C964* | Nonsense Mutation (SNP) | VAF 156/685 reads (23%) | catalogued as COSV58888808; called by muse, mutect2, varscan2
- CTNND2 | c.2891G>A p.C964Y | Missense Mutation (SNP) | VAF 155/684 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58888817; called by muse, mutect2, varscan2
- EEA1 | c.4027C>T p.Q1343* | Nonsense Mutation (SNP) | VAF 148/428 reads (35%) | catalogued as COSV59285782; called by muse, mutect2, varscan2
- EIF2S3 | c.760C>A p.P254T | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as COSV53406702; called by muse, mutect2, varscan2
- EN1 | c.1125G>T p.Q375H | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV54631114; called by muse, mutect2, varscan2
- FGF10 | c.257C>T p.T86I | Missense Mutation (SNP) | VAF 88/438 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV52934550; called by muse, mutect2, varscan2
- FGF18 | c.60C>A p.F20L | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV51126333; called by muse, mutect2
- FRMPD2 | c.1287G>T p.K429N | Missense Mutation (SNP) | VAF 36/403 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100563398; called by muse, mutect2
- FRRS1 | c.833del p.R278Qfs*5 | Frame Shift Del (DEL) | VAF 27/82 reads (33%) | catalogued as COSV54922103, COSV54923301; called by mutect2, pindel, varscan2
- FSHR | c.472C>G p.H158D | Missense Mutation (SNP) | VAF 82/867 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.181); catalogued as COSV100436323, COSV100436573; called by muse, mutect2
- GCDH | c.233G>C p.R78T | Missense Mutation (SNP) | VAF 67/185 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.093); catalogued as COSV53435009; called by muse, mutect2, varscan2
- HEATR3 | c.1885G>C p.A629P | Missense Mutation (SNP) | VAF 80/183 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.203); catalogued as COSV53529229; called by muse, mutect2, varscan2
- IMMP1L | c.228T>A p.D76E | Missense Mutation (SNP) | VAF 6/165 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV99541403; called by muse, mutect2
- KBTBD12 | c.1339C>A p.Q447K | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.965); catalogued as COSV100675325; called by muse, mutect2
- KBTBD6 | c.1326dup p.R443Afs*8 | Frame Shift Ins (INS) | VAF 19/151 reads (13%) | catalogued as rs774820321; called by mutect2, varscan2
- KLHL42 | c.1194dup p.C399Vfs*43 | Frame Shift Ins (INS) | VAF 8/54 reads (15%) | catalogued as rs749194179; called by mutect2, varscan2
- LETM1 | c.432dup p.A145Rfs*61 | Frame Shift Ins (INS) | VAF 14/98 reads (14%) | catalogued as rs745839823; called by mutect2, varscan2
- MICAL2 | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 124/767 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56320336; called by muse, mutect2, varscan2
- MPV17 | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.077); catalogued as rs773077701, COSV99274102; ClinVar: uncertain significance; called by muse, mutect2
- MRC1 | c.1862C>A p.A621E | Missense Mutation (SNP) | VAF 258/774 reads (33%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.769); catalogued as COSV53470194; called by muse, mutect2, varscan2
- MUC17 | c.13244G>A p.R4415H | Missense Mutation (SNP) | VAF 253/413 reads (61%) | SIFT tolerated (0.52); PolyPhen benign (0.038); catalogued as rs374087771; called by muse, mutect2, varscan2
- NECTIN3 | c.1034G>T p.G345V | Missense Mutation (SNP) | VAF 92/399 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60551292, COSV60552039; called by muse, mutect2, varscan2
- NINL | c.682G>T p.V228F | Missense Mutation (SNP) | VAF 33/41 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs777310048, COSV54002583, COSV54003728; called by muse, mutect2, varscan2
- NRXN2 | c.808dup p.A270Gfs*27 | Frame Shift Ins (INS) | VAF 79/430 reads (18%) | catalogued as rs754860965; called by mutect2, varscan2
- NYNRIN | c.4844C>T p.S1615L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as rs746050976, COSV66842433; called by muse, mutect2, varscan2
- OR10G9 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 145/363 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0.047); catalogued as rs1460004571, COSV66686261; called by muse, mutect2, varscan2
- OR10Z1 | c.838G>T p.V280L | Missense Mutation (SNP) | VAF 102/336 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.267); catalogued as COSV63524848; called by muse, varscan2
- PCDHA11 | c.1681G>A p.A561T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.094); catalogued as COSV56501337; called by muse, mutect2, varscan2
- PDE4DIP | c.4465C>T p.R1489W | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs140637862; called by muse, mutect2, varscan2
- RELN | c.6174C>A p.C2058* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as COSV59002110; called by muse, mutect2, varscan2
- SEMA5A | c.823C>A p.R275S | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.393); catalogued as COSV101228641, COSV66793084; called by muse, mutect2, varscan2
- SH2D4B | c.246C>G p.I82M | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV100213431; called by muse, mutect2
- SPDYE1 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 53/193 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.077); catalogued as COSV51670455; called by muse, mutect2, varscan2
- SULF1 | c.2291C>A p.S764Y | Missense Mutation (SNP) | VAF 320/757 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV52681284; called by muse, mutect2, varscan2
- TAF1C | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs567236392, COSV58986369; called by muse, mutect2, varscan2
- TMEM255B | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 164/444 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.65); catalogued as COSV64703904; called by muse, mutect2, varscan2
- TRIM35 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 34/922 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs753753799, COSV100542626; called by muse, mutect2
- UMOD | c.840dup p.E281Rfs*18 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | catalogued as rs774365088; called by pindel, varscan2
- USP20 | c.367_368del p.P123Yfs*5 | Frame Shift Del (DEL) | VAF 93/113 reads (82%) | catalogued as COSV59613904; called by mutect2, pindel, varscan2
- GATA3 | c.1299_1300dup p.H434Pfs*42 | Frame Shift Ins (INS) | VAF 28/83 reads (34%) | called by mutect2, pindel, varscan2
- BLZF1 | c.510G>T p.G170= | Silent (SNP) | VAF 51/278 reads (18%) | catalogued as COSV61393561, COSV61393800; called by muse, mutect2, varscan2
- CFAP65 | c.1074C>T p.A358= | Silent (SNP) | VAF 34/58 reads (59%) | catalogued as rs968457113, COSV55390325; called by muse, mutect2, varscan2
- CTNNBL1 | c.999C>T p.G333= | Silent (SNP) | VAF 166/597 reads (28%) | catalogued as rs373840043; called by muse, mutect2, varscan2
- DCHS1 | c.1704G>C p.L568= | Silent (SNP) | VAF 17/155 reads (11%) | catalogued as COSV100201317; called by muse, mutect2
- GRIP2 | c.459C>A p.G153= (on ENST00000619221; = p.G56= on NM_001080423.4) | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV99816831; called by muse, mutect2
- MAGIX | c.466C>T p.L156= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as COSV66256034; called by muse, mutect2, varscan2
- MAP3K21 | c.1185C>A p.L395= | Silent (SNP) | VAF 249/554 reads (45%) | catalogued as rs750139290, COSV100786274, COSV64044625; called by muse, mutect2, varscan2
- NAIF1 | c.822C>A p.A274= | Silent (SNP) | VAF 42/58 reads (72%) | catalogued as COSV66090912; called by muse, mutect2, varscan2
- NEUROD4 | c.474G>C p.L158= | Silent (SNP) | VAF 7/87 reads (8%) | catalogued as COSV54474082, COSV99669650; called by muse, mutect2
- PAPSS2 | c.1794C>A p.P598= | Silent (SNP) | VAF 35/89 reads (39%) | catalogued as COSV63263352; called by muse, mutect2, varscan2
- PCNX3 | c.2397G>A p.L799= | Silent (SNP) | VAF 24/433 reads (6%) | catalogued as rs746351113, COSV100855890; called by muse, mutect2
- PTPRB | c.195C>A p.A65= | Silent (SNP) | VAF 18/302 reads (6%) | catalogued as COSV54232137, COSV54239040; called by muse, mutect2
- RPAP2 | c.609A>G p.Q203= | Silent (SNP) | VAF 76/218 reads (35%) | catalogued as COSV72509333; called by muse, mutect2, varscan2
- SEMA3D | c.552T>C p.P184= | Silent (SNP) | VAF 30/318 reads (9%) | catalogued as COSV99405576; called by muse, mutect2
- TSSK3 | c.655C>T p.L219= | Silent (SNP) | VAF 5/99 reads (5%) | catalogued as COSV100344303; called by muse, mutect2
- WNT7A | c.495C>T p.V165= | Silent (SNP) | VAF 83/129 reads (64%) | catalogued as COSV53198849; called by muse, mutect2, varscan2
- MAZ | c.1280-519A>G | Intron (SNP) | VAF 4/18 reads (22%) | catalogued as COSV99360737; called by muse, mutect2, varscan2
- MSI2 | c.*2C>A | 3'UTR (SNP) | VAF 191/841 reads (23%) | catalogued as COSV99401374; called by muse, mutect2, varscan2
